Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA6Q, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA6Q-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY REPORT
*** Addendum ***

Patient Name:

Accession #:

Med. Rec. #:

Date of Procedure:

DOB: (Age:

Location:

Date of Receipt:

Gender:

F

Service:

Urology

Date of Report:

Ref. Physician: .

Account #:

Patient Address:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

History of T2 bladder carcinoma with focal squamous differentiation.

Specimens Submitted:

- 1: Right common iliac lymph nodes
- 2: Left common iliac lymph nodes
- 3: Right distal lymph nodes
- 4: Bladder, uterus, tubes and ovaries, peri-vesicle lymph nodes
- 5: Left distal pelvic lymph nodes
- 6: Pre-sacral lymph nodes
- 7: Abdominal wall skin scar
- 8: Left distal ureter
- 9: Right distal ureter

DIAGNOSIS:

1. Right common iliac lymph nodes:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 5

2. Left common iliac lymph nodes:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 7

3. Right distal lymph nodes:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 12

Comment: AE1/AE3 immunohistochemical staining on a selected slide fails to reveal carcinoma in lymph nodes.

4. Bladder, uterus, tubes and ovaries, peri-vesicle lymph nodes:

Tumor Type:

Invasive urothelial carcinoma, NOS
with focal squamous features

*TCGAs 3
Carcinoma, urothelial NOS
8/20/13
Site: Bladder, posterior wall
067.4
QJ 4/30/14*

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

[page 2 of 7]
SURGICAL PATHOLOGY REPORT

Flat (in situ carcinoma)

Pattern of growth of the Invasive component:
Infiltrating

Tumor Multicentricity:
Identified

Bladder Local Invasion:
Perivesical soft tissues

Extravesical Tumor Extension:
Ureters uninvolved
Urethra uninvolved

Vascular Invasion:
Identified

Perineural Invasion:
Not identified

Surgical Margins:
Free of tumor

Non-Neoplastic Mucosa:
Exhibiting chronic cystitis
Exhibiting ulceration

Female Genital Organs:
The endometrium shows atrophy
The myometrium shows a leiomyoma
The right fallopian tube shows an adenofibroma
Remaining genital organs are unremarkable

Perivesical Lymph Nodes:
Not identified

The Pathologic Stage is (AJCC 2002):
pT3 (Invasion of perivesicle soft tissue)

Comment: Immunohistochemical stains for HPV in situ hybridization and p16 fail to reveal an association with HPV.

5. Left distal pelvic lymph nodes:

Lymph Node Dissection:
Metastatic urothelial carcinoma
Number of lymph nodes examined: 4
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 1.6cm.
Size of the largest metastatic focus : 1.6 cm.
Extranodal extension is not identified

6. Pre-sacral lymph nodes:

Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 5

7. Skin, abdominal wall skin scar:

- Benign skin with scar.

8. Left distal ureter, resection:

- Benign segment of ureter.

[page 3 of 7]
SURGICAL PATHOLOGY REPORT

9. Right distal ureter, resection:

- Benign segment of ureter.

Note: Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Procedures/Addenda:

Addendum

Date Ordered:

Status: Ordered

-

Gross Description:

1) The specimen is received fresh, labeled "Right common iliac lymph nodes" and consists of a gray-tan rubbery nodule measuring 1.7 x 0.5 x 0.3 cm. Two additional possible lymph nodes identified measuring 0.4 and 0.5 cm. The lymph node is entirely submitted. The additional tissue is submitted.

Summary of sections:

LN - lymph node

RS - possible lymph nodes

2) The specimen is received fresh, labeled "Left common iliac lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 1.0 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes (7)

BLN - bisected lymph node (1)

3) The specimen is received fresh, labeled "Right distal lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 2.1 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes (10)

BLN - bisected lymph nodes (2)

[page 4 of 7]
SURGICAL PATHOLOGY REPORT

4) The specimen is received fresh, labeled "Bladder, uterus, tubes and ovaries, peri vesicles lymph node". It consist of a radical cystectomy specimen with attached uterus and bilateral adnexa s organs measuring 12.0cm from superior to inferior, 9.0 cm laterally and 4.0 cm from anterior to posterior. The bladder measures 8.0 x 7.0 x 2.0 cm, the uterus measures 8.0 x 4.0 x 2.0 cm, the right ovary measures 4.5 x 1.5 x 0.7 cm, the right fallopian tube shows to blind segments measuring 3.0 and 3.5cm from proximal to distal, the left ovary measures 3.5 x 1.2 x 0.7 cm, and the left fallopian tube shows to blind ends measuring 2.0 and 3.7 cm form proximal to distal. The portion of vaginal cuff measures 3.0 x 2.7 x 0.5 cm. The distal urethra and the vaginal cuff margin are shaved and submitted. The ureteric stumps measure 3.0 x 0.4 cm and show a 0.1 cm pinpoint lumen. The specimen is inked black(anteriorly), blue posteriorly and the bladder is opened anteriorly to reveal four white tan lesions, designated as follows: Prominent nodular lesion located on the left posterior wall measuring 1.7 x 1.5 x 0.7 cm, arbitrarily designated as lesion A. There is a 2.2 x 1.7cm lesion located 1.7cm from right ureter orifice, embedded in a diverticulum with irregular indurated borders, located on the right posterior wall, designated as lesion B, which measures 1.2 cm in depth, and 0.5cm from the blue inked peri-adipose tissue. The lesion lies 1.0 cm from the right ureteral orifice. A third white tan nodular lesion is identified on the right anterior wall, measuring 0.7 x 0.6 x 0.6cm, designated as C. A fourth nodular lesion is identified on the right lateral superior wall, measuring 1.2 x 0.9 x 0.7 cm designated as D. Multiple pink red, suspicious scar-like areas are identified varying from 0.4 to 0.7cm in greatest dimension.. The remaining bladder mucosa shows a pink tan, edematous focally hemorrhagic surface. Discrete perivesical lymph nodes are not. The uterus is bivalved to reveal a 0.1cm pink tan endometrial surface. The ovaries and fallopian tubes show a multicystic cut surface. Tissue was submitted for TPS. Gross photographs are taken. Representative sections are submitted.

Summary of sections:

UM - distal urethra
RUM - right ureter margin
LUM - left ureter margin
RUO - right ureteric orifice
LUO - left ureteric orifice
LPW - left posterior wall
LAW - left anterior wall
RPW- right posterior wall
RAW - right anterior wall
TRI - trigone
DOME - dome
F - perivesical fat
EMM - endomyometrium
CX - cervix
DVM - distal vaginal margin
RTO - right tube and ovary
LTO - left tube and ovary
LA – lesion A
LB – lesion B
LC – lesion C
LD – lesion D
SA – suspicious mucosal areas
LN - whole lymph nodes
BLN - bisected lymph nodes

5) The specimen is received in formalin, labeled "Left distal pelvic lymph nodes" and consists of three gray tan firm, matted positive lymph nodes. The largest positive lymph node measures 3.0 x 1.5 x 1.3cm . All identified lymph nodes are submitted. Sample was given to TPS protocol.

Summary of sections:

LN - lymph nodes
RLN -representative lymph node

6)The specimen is received in formalin, labeled "Pre sacral lymph nodes" and consists of five tan blue firm lymph nodes ranging from 0.7 to 1.4 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

[page 5 of 7]
SURGICAL PATHOLOGY REPORT

7) The specimen is received in formalin labeled "Abdominal wall skin scar." It consists of a strip of white-tan skin measuring 8.5 x 1.0 x 1.0 cm. The surface of the skin shows scarred appearance. Representative sections are submitted.

Summary of sections:

U-undesignated

8) The specimen is received in formalin, labeled "Left distal ureter, unclipped end is margin" and consists of a tan-white tubular tissue fragment measuring 5.2 cm in length and 0.6 cm in diameter, with attached adipose tissue measuring 0.8 cm in thickness. There is a clip at one end of the specimen. On cut section, the mucosa appears white-tan and grossly unremarkable. The specimen is sequentially sectioned from the clipped end to the non-clipped end and submitted entirely.

Summary of sections:

CE - clipped end

UCE - non-clipped end

SS - sequential sections from clipped to non-clipped end

9) The specimen is received in formalin, labeled "Right distal ureter, unclipped end is margin" and consists of a tan-white tubular tissue fragment measuring 5.8 cm in length and 0.6 cm in diameter, with attached adipose tissue measuring 0.8 cm in thickness. There is a clip at one end of the specimen. On cut section, the mucosa appears white-tan and grossly unremarkable. The specimen is sequentially sectioned from the clipped end to the non-clipped end and submitted entirely.

Summary of sections:

CE - clipped end

UCE - non-clipped end

SS - sequential sections from clipped to non-clipped end

Summary of Sections:

Part 1: Right common iliac lymph nodes

Blocks	Block Designation	PCs
1	LN	1
1	RS	2

Part 2: Left common iliac lymph nodes

Blocks	Block Designation	PCs
1	BLN	2
2	LN	7

Part 3: Right distal lymph nodes

Blocks	Block Designation	PCs
2	BLN	4
2	LN	10

Part 4: Bladder, uterus, tubes and ovaries, peri-vesicle lymph nodes

Blocks	Block Designation	PCs
1	CX	2
1	DOVE	1
1	DVM	1
1	EMM	2
6	LA	6
1	LAW	1

[page 6 of 7]
SURGICAL PATHOLOGY REPORT

5	LB	5
2	LC	2
4	LD	4
1	LPW	1
1	LTO	4
1	LUM	1
1	LUO	1
1	RAW	1
1	RPW	1
1	RTO	4
1	RUM	1
1	RUO	1
2	SA	6
1	TRI	1
1	UM	1

Part 5: Left distal pelvic lymph nodes

Blocks	Block Designation	PCs
1	LN	1
1	RLN	1

Part 6: Pre-sacral lymph nodes

Blocks	Block Designation	PCs
2	LN	5

Part 7: Abdominal wall skin scar

Blocks	Block Designation	PCs
1	U	1

Part 8: Left distal ureter

Blocks	Block Designation	PCs
1	CE	1
4	SS	4
1	UCE	1

Part 9: Right distal ureter

Blocks	Block Designation	PCs
1	CE	1
4	SS	4
1	UCE	1

Special Studies:**Result**

Special Stain
KP1 (CD68)
AE1:AE3
IMM RECUT
NEG CONT
CD30(BERH2)
CD3 (Leu4)
CD20 (L26)
EBER-ISH
P16.
HPV-ISH.
P16.
HPV-ISH.
P16.
HPV-ISH.

Comment

[page 7 of 7]
SURGICAL PATHOLOGY REPORT

IMM RECUT
NEG CONT
IMM RECUT
NEG CONT
IMM RECUT
NEG CONT
RECUT
RECUT
RECUT
RECUT
RECUT
RECUT
RECUT
RECUT
RECUT
P16.
HPV-ISH.
IMM RECUT
NEG CONT

Source: NCI Genomic Data Commons file ec76f7f3-3bc9-476d-b8a8-b91bc435b41f (TCGA-DK-AA6Q.1D50AD73-3AE6-427F-92D8-518FE4BD4B51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).